Somatic mutation profile of tumor specimen C3L-00263-04 (aliquot CPT0011710007) from CPTAC case C3L-00263, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 79.8 years (29,164 days).
Specimen C3L-00263-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3591ca7-099f-4b20-a065-12f6f5f2d075.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00263-31 (Blood Derived Normal), aliquot CPT0012420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f0a5987-1104-41c4-bea4-ef910401c07c

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 20/306 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 14/408 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2
- WWTR1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.53); catalogued as rs1330547066; called by muse, mutect2
- RFLNB | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2
- ATG2B | c.5403T>C p.F1801= | Silent (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- OGDHL | c.816G>C p.V272= | Silent (SNP) | VAF 6/152 reads (4%) | called by muse, mutect2
